Somatic mutation profile of tumor specimen MP2PRT-PARPGE-TMP1-A (aliquot MP2PRT-PARPGE-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPGE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (446 days).
Specimen MP2PRT-PARPGE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 477ae4c1-6ddb-48cd-acca-dfd2c6e0caa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPGE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPGE-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43b1bd26-ca06-4718-b3e9-8a1d126ef2db

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 82/398 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MICALL2 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 93/790 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.613); catalogued as rs766521907; called by muse, mutect2, varscan2
- RBM19 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 68/672 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as rs746667832, COSV55687546; called by muse, mutect2, varscan2
- AATK | c.618A>C p.P206= (on ENST00000326724 / NM_001080395.3; = p.P103= on NM_004920.2) | Silent (SNP) | VAF 110/1104 reads (10%) | called by muse, mutect2
